Gene-level copy-number profile of tumor specimen TCGA-19-A60I-01A from TCGA case TCGA-19-A60I, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 39.5 years (14,437 days).
Specimen TCGA-19-A60I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.7cdf71c2-270c-44ed-aa5e-aa0be43bb0e9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-19-A60I-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f6c6b1a9-9125-45a4-bdab-ac2fa0eba975

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 8,781; copy number 2: 45,542; copy number 3: 5,334; copy number 4: 56; copy number 7: 18; copy number 9: 14; copy number 26: 20; copy number 27: 7; copy number 28: 11; copy number 29: 31.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-19-A60I-01A-12D-A33S-01): tumor purity 0.91, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 101 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:10,306,465–10,991,797, 18 genes, copy number 27–28 (within-gene range 27–46): RN7SL731P, AL139424.3, AL139424.2, PGD, AL139424.1, CENPS-CORT, CENPS, CORT, DFFA, AL354956.1, PEX14, AL139423.2, RN7SL614P, CASZ1, AL139423.1, HSPE1P24, C1orf127, CFL1P6.
- chr1:223,538,007–223,665,723, 2 genes, copy number 26 (within-gene range 2–26): CAPN8, SNRPEP10.
- chr2:15,869,939–16,333,978, 14 genes, copy number 9 (within-gene range 2–9): RPLP1P5, AC010145.2, MYCNOS, MYCNUT, MYCN, RN7SL104P, AC010145.1, GACAT3, AC130710.1, AC174048.1, AC142283.1, AC010745.1, AC010745.2, AC010745.3.
- chr4:53,377,839–54,295,272, 1 gene, copy number 7 (within-gene range 2–7): AC058822.1.
- chr4:53,899,871–54,740,715, 17 genes, copy number 7: AC105384.1, AC105384.2, RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA, LINC02283, AC098587.1, AC098868.1, LINC02260, KIT.
- chr6:35,443,044–36,024,868, 23 genes, copy number 29 (within-gene range 2–29): MKRN6P, FANCE, RPL10A, MIR7111, TEAD3, TULP1, AL033519.4, AL033519.3, FKBP5, AL033519.2, AL033519.5, AL033519.1, MIR5690, AL157823.2, ARMC12, AL157823.1, CLPSL2, CLPSL1, CLPS, LHFPL5, SRPK1, SLC26A8, DPRXP2.
- chr7:54,752,250–55,260,256, 8 genes, copy number 29: SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2.
- chr13:113,208,193–113,751,089, 18 genes, copy number 26: CUL4A, MIR8075, LDHBP1, LAMP1, GRTP1, AL136221.1, GRTP1-AS1, ADPRHL1, DCUN1D2, DCUN1D2-AS, RNU1-16P, TMCO3, AL442125.2, AL442125.1, TFDP1, ATP4B, GRK1, LINC00552.

Autosomal genes at a single copy (total copy number 1): 6,394. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
